Somatic mutation profile of tumor specimen MP2PRT-PARSPU-TMP1-A (aliquot MP2PRT-PARSPU-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PARSPU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.2 years (451 days).
Specimen MP2PRT-PARSPU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11bb563a-496c-4359-b86e-348f890d7579.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARSPU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARSPU-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/452d0c14-a0a9-4b36-aebb-10643aec867f

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2, Splice Region 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IGKV3-11 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 54/432 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs759854210; called by muse, mutect2, varscan2
- IL20RA | c.579G>A p.T193= | Splice Region (SNP) | VAF 50/179 reads (28%) | catalogued as rs375320839, COSV57356204; called by muse, mutect2, varscan2
- KRTAP10-6 | c.693_707dup p.V237_P241dup | In Frame Ins (INS) | VAF 143/839 reads (17%) | catalogued as rs781893490; called by mutect2, varscan2
- MYH7B | c.3278G>A p.R1093H | Missense Mutation (SNP) | VAF 126/505 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768531311, COSV53425604; called by muse, mutect2, varscan2
- SIGLEC14 | c.1181G>A p.R394K | Missense Mutation (SNP) | VAF 41/597 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs750167130; called by muse, mutect2
- TRO | c.2931C>A p.A977= | Silent (SNP) | VAF 26/632 reads (4%) | called by muse, mutect2
- ZNF765 | c.1566C>T p.H522= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs146474834; called by muse, mutect2, varscan2
